Somatic mutation profile of tumor specimen 0DVZEG from CCDI case PBCMET, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Retinoblastoma, NOS; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 1.8 years (642 days).
Specimen 0DVZEG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a77acdbb-ed76-4d06-9e48-d659a5bfa2a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZE9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d87e4bcd-42a5-4005-bcd9-7ad2539437e2

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 2, Silent 2, Intron 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC22A14 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 211/520 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756231072, COSV56197608; called by muse, mutect2, varscan2
- ACOX2 | c.83T>C p.M28T | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- APOL5 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 32/576 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- CDH22 | c.679C>G p.R227G | Missense Mutation (SNP) | VAF 307/636 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 52/944 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- S100A7A | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 92/1292 reads (7%) | called by muse, mutect2
- SH3YL1 | c.743A>T p.Q248L | Missense Mutation (SNP) | VAF 62/1098 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- USP6NL | c.723A>G p.I241M | Missense Mutation (SNP) | VAF 121/495 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 34/665 reads (5%) | called by muse, mutect2
- USF3 | c.3408A>T p.A1136= | Silent (SNP) | VAF 35/474 reads (7%) | catalogued as COSV57072566; called by muse, mutect2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 40/410 reads (10%) | called by muse, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 14/181 reads (8%) | called by muse, mutect2
- FAM117B | c.*26C>T | 3'UTR (SNP) | VAF 16/249 reads (6%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 7/33 reads (21%) | called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 22/135 reads (16%) | called by muse, varscan2
